Somatic mutation profile of tumor specimen TCGA-UF-A7J9-01A (aliquot TCGA-UF-A7J9-01A-12D-A34J-08) from TCGA case TCGA-UF-A7J9, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 75.2 years (27,459 days).
Specimen TCGA-UF-A7J9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e6ec12d1-d88e-40fd-ad99-98df2a32f6e1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7J9-10A (Blood Derived Normal), aliquot TCGA-UF-A7J9-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fceceaf9-c8ef-49cd-ad91-ce4d7608a534

The open-access MAF lists 271 somatic variants for this specimen: 198 protein-altering or splice-affecting, 65 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 169, Silent 65, Nonsense Mutation 15, Frame Shift Del 7, RNA 4, Splice Site 3, Intron 3, Frame Shift Ins 2, Splice Region 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXW7 | c.1637C>G p.S546* (on ENST00000281708 / NM_001349798.2; = p.S466* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 42/115 reads (37%) | hotspot (GDC flag); catalogued as COSV55905633, COSV99656643, COSV99660447; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 15/103 reads (15%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.733G>T p.G245C | Missense Mutation (SNP) | VAF 34/84 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934575, CM010463, CM900210, CM920674, COSV52661744, COSV52661877, COSV52713951, COSV52839866; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADCY4 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.87); catalogued as COSV99353433; called by muse, mutect2, varscan2
- AFG3L2 | c.779C>T p.T260M | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs374353312; called by mutect2, varscan2
- APBA1 | c.1515+2T>G p.X505_splice | Splice Site (SNP) | VAF 70/139 reads (50%) | catalogued as COSV99597034; called by muse, mutect2, varscan2
- APEX2 | c.742C>T p.R248C | Missense Mutation (SNP) | VAF 10/18 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58188125; called by muse, mutect2, varscan2
- APOB | c.5587G>C p.E1863Q | Missense Mutation (SNP) | VAF 41/161 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.09); catalogued as COSV99267706; called by muse, mutect2, varscan2
- ARHGAP39 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.981); catalogued as rs903898384, COSV99432183; called by muse, mutect2, varscan2
- ARPIN | c.388G>A p.E130K | Missense Mutation (SNP) | VAF 19/95 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as COSV100673480; called by muse, mutect2, varscan2
- ASPRV1 | c.771G>A p.W257* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | catalogued as COSV100208616; called by muse, mutect2, varscan2
- ATR | c.3727G>C p.D1243H | Missense Mutation (SNP) | VAF 15/159 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as COSV100638553; called by muse, mutect2, varscan2
- BCLAF1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.402); catalogued as rs763501395, COSV100786953, COSV62145177; called by muse, mutect2, varscan2
- BDKRB2 | c.969C>A p.S323R | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV100021433; called by muse, mutect2, varscan2
- BICC1 | c.2768G>A p.R923K | Missense Mutation (SNP) | VAF 12/133 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV100874905; called by muse, mutect2
- BMP1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.15); PolyPhen benign (0.102); catalogued as rs770440497, COSV60478574, COSV60480301; called by muse, mutect2, varscan2
- BSDC1 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as rs747435307, COSV100345027; called by muse, mutect2, varscan2
- CACNA2D1 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 25/161 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100667173; called by muse, mutect2, varscan2
- CACNG3 | c.304A>T p.R102W | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99137038; called by muse, mutect2, varscan2
- CAPRIN2 | c.2495A>T p.Y832F | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.86); catalogued as rs754556464, COSV99195665; called by muse, mutect2, varscan2
- CAPRIN2 | c.2494T>A p.Y832N | Missense Mutation (SNP) | VAF 51/174 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV99195667; called by muse, mutect2, varscan2
- CATSPERD | c.154A>G p.T52A | Missense Mutation (SNP) | VAF 12/168 reads (7%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as COSV101062783; called by muse, mutect2
- CCDC136 | c.367G>T p.E123* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV99923135; called by muse, mutect2, varscan2
- CDKN2A | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1554653960, CM970253, COSV100447835, COSV58692451; ClinVar: uncertain significance; called by mutect2, varscan2
- CDKN2A | c.350del p.L117Rfs*29 | Frame Shift Del (DEL) | VAF 16/49 reads (33%) | catalogued as COSV58724125; called by mutect2, varscan2
- CHRD | c.2554+1G>C p.X852_splice | Splice Site (SNP) | VAF 6/24 reads (25%) | catalogued as COSV99200743; called by muse, mutect2
- CHRNA4 | c.1815G>C p.M605I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.125); catalogued as COSV100937475; called by muse, mutect2, varscan2
- CIP2A | c.1455G>C p.L485F | Missense Mutation (SNP) | VAF 27/243 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772103726, COSV99842627; called by muse, mutect2, varscan2
- CNTN4 | c.2543A>C p.E848A | Missense Mutation (SNP) | VAF 4/54 reads (7%) | SIFT tolerated (0.18); PolyPhen benign (0.403); catalogued as COSV100639674; called by muse, mutect2
- CNTN4 | c.2544A>T p.E848D | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.013); catalogued as COSV100639675; called by muse, mutect2
- CNTNAP5 | c.746C>T p.A249V | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0.054); catalogued as rs377323989, COSV70471381; called by muse, mutect2
- COP1 | c.274G>T p.A92S | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.014); catalogued as COSV100443859; called by muse, mutect2
- CUBN | c.9561del p.W3187* | Frame Shift Del (DEL) | VAF 23/127 reads (18%) | catalogued as COSV100911905; called by mutect2, pindel, varscan2
- DDX18 | c.1065A>G p.P355= | Splice Region (SNP) | VAF 9/60 reads (15%) | catalogued as rs755314412, COSV99604759; called by muse, mutect2, varscan2
- DDX42 | c.1369A>G p.I457V | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT tolerated (0.83); PolyPhen benign (0.026); catalogued as rs747552625, COSV100835053; called by muse, mutect2, varscan2
- DEPP1 | c.424A>T p.S142C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.54); catalogued as COSV100024492; called by muse, mutect2, varscan2
- DHX35 | c.1804G>T p.D602Y | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99327279; called by muse, mutect2, varscan2
- DPYSL2 | c.410T>A p.L137Q | Missense Mutation (SNP) | VAF 17/74 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100234176; called by muse, mutect2, varscan2
- DST | c.4366A>G p.I1456V (on ENST00000361203 / NM_001374722.1; = p.I1130V on NM_015548.5) | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.3); PolyPhen benign (0.331); catalogued as rs756231158, COSV99759534; called by muse, mutect2, varscan2
- EARS2 | c.1442A>G p.Y481C | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as COSV101492192; called by muse, mutect2, varscan2
- EEF1E1 | c.16G>C p.E6Q | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as rs1452016659, COSV101121268; called by muse, mutect2
- EIF2AK1 | c.826A>T p.S276C | Missense Mutation (SNP) | VAF 36/169 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.635); catalogued as COSV99552254; called by muse, mutect2, varscan2
- EIF4G1 | c.4603T>G p.L1535V (on ENST00000346169 / NM_198241.3; = p.L1340V on NM_004953.5) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100072251; called by muse, mutect2, varscan2
- ELFN2 | c.1589C>G p.S530W | Missense Mutation (SNP) | VAF 111/260 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101297626, COSV68744379; called by muse, mutect2, varscan2
- EPHA5 | c.812C>T p.P271L | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99900979; called by muse, mutect2, varscan2
- EPHA7 | c.184G>C p.D62H | Missense Mutation (SNP) | VAF 13/124 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100992520; called by muse, mutect2, varscan2
- ERMN | c.679C>A p.P227T | Missense Mutation (SNP) | VAF 47/240 reads (20%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.913); catalogued as COSV101263064; called by muse, mutect2, varscan2
- F13B | c.1000G>T p.V334L | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.41); PolyPhen benign (0.014); catalogued as rs1180049774; called by muse, mutect2, varscan2
- FAAH2 | c.333G>T p.Q111H | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100887428; called by muse, varscan2
- FAAH2 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | catalogued as COSV100887429; called by muse, varscan2
- FAM133A | c.119C>T p.T40I | Missense Mutation (SNP) | VAF 22/42 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.148); catalogued as COSV59076101; called by muse, mutect2, varscan2
- FAP | c.908G>T p.R303L | Missense Mutation (SNP) | VAF 34/177 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as COSV51861034, COSV51868981; called by muse, mutect2, varscan2
- FAT1 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 46/371 reads (12%) | catalogued as rs547340067, COSV71672032; called by muse, mutect2, varscan2
- FFAR3 | c.315C>G p.F105L | Missense Mutation (SNP) | VAF 32/192 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.129); catalogued as COSV100588299; called by muse, mutect2, varscan2
- FGA | c.644C>T p.S215F | Missense Mutation (SNP) | VAF 10/151 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.368); catalogued as COSV100120690; called by muse, mutect2
- FNDC1 | c.1189C>G p.L397V | Missense Mutation (SNP) | VAF 18/189 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.963); catalogued as COSV99796648; called by muse, mutect2, varscan2
- G6PD | c.1280G>C p.R427T | Missense Mutation (SNP) | VAF 94/189 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV63703662; called by muse, mutect2, varscan2
- GAMT | c.573G>C p.E191D | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.735); catalogued as COSV99282996; called by muse, mutect2, varscan2
- GJA10 | c.1529T>C p.V510A | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1240534179, COSV101005435; called by muse, mutect2
- GPR1 | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.145); catalogued as COSV101329866; called by muse, varscan2
- GPR50 | c.1544C>T p.P515L | Missense Mutation (SNP) | VAF 53/117 reads (45%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0); catalogued as rs1388397532, COSV99506560; called by muse, mutect2, varscan2
- GRIA3 | c.790G>A p.G264R | Missense Mutation (SNP) | VAF 51/103 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52079993; called by muse, mutect2, varscan2
- HCN1 | c.1619A>T p.E540V | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100302068; called by muse, mutect2, varscan2
- HERC1 | c.12967C>A p.L4323I | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV101496858; called by muse, mutect2, varscan2
- HMCN1 | c.16547G>T p.C5516F | Missense Mutation (SNP) | VAF 32/122 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs767885484, COSV99634943; called by muse, mutect2, varscan2
- HTN1 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.975); catalogued as rs552053383, COSV55895457; called by muse, mutect2, varscan2
- IDE | c.463C>G p.H155D | Missense Mutation (SNP) | VAF 18/141 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.248); catalogued as COSV99794374; called by muse, mutect2, varscan2
- IMPG1 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 11/173 reads (6%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.654); catalogued as COSV100886629, COSV64060955; called by muse, mutect2
- IQCJ-SCHIP1 | c.236C>G p.S79* | Nonsense Mutation (SNP) | VAF 24/198 reads (12%) | catalogued as COSV67332692; called by muse, mutect2, varscan2
- KATNBL1 | c.489G>C p.M163I | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV99854505; called by muse, mutect2, varscan2
- KCNA3 | c.1663A>T p.T555S | Missense Mutation (SNP) | VAF 49/174 reads (28%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.039); catalogued as COSV100871222, COSV100871305; called by muse, mutect2, varscan2
- KCNG1 | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65368469; called by muse, mutect2, varscan2
- KCTD16 | c.1090G>A p.D364N | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV101568876, COSV72578143; called by muse, mutect2, varscan2
- KIF1A | c.1813G>A p.E605K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.17); PolyPhen benign (0.279); catalogued as COSV100242209; called by muse, varscan2
- KIFAP3 | c.825G>T p.Q275H | Missense Mutation (SNP) | VAF 52/324 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100847147; called by muse, mutect2, varscan2
- KMT2C | c.10606C>T p.H3536Y | Missense Mutation (SNP) | VAF 14/109 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.197); catalogued as rs375465800; called by muse, mutect2, varscan2
- LAMA4 | c.2095G>A p.G699S (on ENST00000230538 / NM_001105206.3; = p.G692S on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.007); catalogued as COSV100039325, COSV57899806; called by muse, mutect2, varscan2
- LEO1 | c.1406A>T p.N469I | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as COSV100166655; called by muse, mutect2, varscan2
- LILRB5 | c.433G>C p.D145H | Missense Mutation (SNP) | VAF 27/104 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.056); catalogued as COSV60256356, COSV60260489; called by muse, mutect2, varscan2
- LMNB2 | c.1664G>T p.G555V | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV99296089; called by muse, mutect2, varscan2
- LMTK2 | c.121G>T p.A41S | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.115); catalogued as COSV99807631; called by muse, mutect2
- LRP1 | c.7200G>C p.K2400N | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV99677050; called by muse, mutect2, varscan2
- MACROD2 | c.541-1G>A p.X181_splice | Splice Site (SNP) | VAF 49/196 reads (25%) | catalogued as COSV99442224; called by muse, mutect2, varscan2
- MAP2 | c.2593G>T p.E865* | Nonsense Mutation (SNP) | VAF 21/101 reads (21%) | catalogued as COSV99560387; called by muse, mutect2, varscan2
- MEI1 | c.1119C>A p.S373R | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV100300297; called by muse, mutect2, varscan2
- MERTK | c.2821C>G p.L941V | Missense Mutation (SNP) | VAF 26/76 reads (34%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV54931192; called by muse, mutect2, varscan2
- MFAP1 | c.892G>A p.E298K | Missense Mutation (SNP) | VAF 46/204 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.723); catalogued as COSV51038958; called by muse, mutect2, varscan2
- MGAM | c.4830G>C p.Q1610H | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.011); catalogued as COSV101527597, COSV101527729; called by muse, mutect2, varscan2
- MMP16 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54153184; called by muse, mutect2, varscan2
- MMS19 | c.1309C>G p.L437V | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT tolerated (0.3); PolyPhen benign (0.395); catalogued as COSV100513086; called by muse, mutect2, varscan2
- MPP2 | c.923C>T p.P308L (on ENST00000461854 / NM_001278372.2; = p.P284L on NM_005374.5) | Missense Mutation (SNP) | VAF 26/108 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52240966; called by muse, mutect2, varscan2
- MUC16 | c.26848C>A p.Q8950K | Missense Mutation (SNP) | VAF 87/283 reads (31%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.351); catalogued as COSV101201406; called by muse, mutect2, varscan2
- MUC17 | c.1594T>C p.S532P | Missense Mutation (SNP) | VAF 196/830 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV100074902; called by mutect2, varscan2
- MUC17 | c.1595C>A p.S532* | Nonsense Mutation (SNP) | VAF 194/830 reads (23%) | catalogued as COSV100074907; called by mutect2, varscan2
- MYEF2 | c.1292C>T p.S431F | Missense Mutation (SNP) | VAF 103/352 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV99982078; called by muse, mutect2, varscan2
- MYH10 | c.3745G>C p.E1249Q | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV99346200; called by muse, mutect2, varscan2
- NCOR2 | c.2695G>T p.G899W | Missense Mutation (SNP) | VAF 22/104 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.017); catalogued as COSV100657821; called by muse, mutect2, varscan2
- NELL1 | c.2321C>T p.S774L | Missense Mutation (SNP) | VAF 19/195 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV54235127; called by muse, mutect2, varscan2
- NOBOX | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs199538689, COSV56197973; ClinVar: likely benign; called by muse, mutect2, varscan2
- NOL4 | c.757C>G p.H253D | Missense Mutation (SNP) | VAF 43/162 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV99308177; called by muse, mutect2, varscan2
- OLAH | c.58T>C p.Y20H | Missense Mutation (SNP) | VAF 21/115 reads (18%) | SIFT tolerated (0.22); PolyPhen benign (0.079); catalogued as rs1168382909, COSV100984858; called by muse, mutect2, varscan2
- OPN3 | c.868A>T p.I290L | Missense Mutation (SNP) | VAF 40/148 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100087802; called by muse, mutect2, varscan2
- OR14K1 | c.514C>A p.L172I | Missense Mutation (SNP) | VAF 57/312 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV99315209; called by muse, mutect2, varscan2
- OR5D14 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 9/165 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); catalogued as COSV59458314; called by muse, mutect2
- OR5R1 | c.551T>A p.F184Y | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.428); catalogued as COSV100393574; called by muse, mutect2
- OR6K3 | c.216C>A p.H72Q (on ENST00000368146; = p.H56Q on NM_001005327.2) | Missense Mutation (SNP) | VAF 27/263 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs531806414, COSV100933884; called by muse, mutect2, varscan2
- OR8B4 | c.490C>T p.R164* | Nonsense Mutation (SNP) | VAF 11/48 reads (23%) | catalogued as rs1208863555, COSV62069819; called by muse, mutect2, varscan2
- OR8B4 | c.361C>T p.R121C | Missense Mutation (SNP) | VAF 40/110 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.117); catalogued as rs371189371, COSV62069699; called by muse, mutect2, varscan2
- ORM2 | c.323G>C p.R108T | Missense Mutation (SNP) | VAF 6/118 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.053); catalogued as rs1408424137, COSV99407682; called by muse, mutect2
- OSBPL6 | c.2648G>C p.R883T | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs367905415, COSV51931998; called by muse, mutect2, varscan2
- PAPPA | c.4139G>C p.G1380A | Missense Mutation (SNP) | VAF 27/45 reads (60%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV100075183; called by muse, mutect2, varscan2
- PARD6G | c.709A>G p.I237V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.94); PolyPhen benign (0.02); catalogued as rs1243923614, COSV100783465; called by muse, mutect2, varscan2
- PAX3 | c.590C>T p.S197L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1246737713, COSV60587612; called by muse, mutect2, varscan2
- PDPK1 | c.1273G>T p.E425* | Nonsense Mutation (SNP) | VAF 44/193 reads (23%) | catalogued as COSV99239526; called by muse, mutect2, varscan2
- PGK1 | c.96C>G p.N32K | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV100965369; called by muse, mutect2
- PLAC1 | c.631T>A p.S211T | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.56); PolyPhen benign (0.295); catalogued as COSV100821636; called by muse, mutect2, varscan2
- PLG | c.1843G>C p.E615Q | Missense Mutation (SNP) | VAF 26/141 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as COSV100369518, COSV100369588; called by muse, mutect2, varscan2
- PNLIP | c.746T>G p.V249G | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as COSV100981958; called by muse, mutect2, varscan2
- POP4 | c.344G>T p.S115I | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as COSV99694600, COSV99694626; called by muse, mutect2, varscan2
- PPFIA2 | c.2820G>C p.Q940H | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV100335043; called by muse, varscan2
- PPL | c.3828C>G p.I1276M | Missense Mutation (SNP) | VAF 63/274 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV99278565; called by muse, mutect2, varscan2
- PPL | c.3425C>T p.A1142V | Missense Mutation (SNP) | VAF 28/97 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.195); catalogued as COSV99278566; called by muse, mutect2, varscan2
- PPP1R2 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 60/260 reads (23%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV100113423; called by muse, mutect2, varscan2
- PRDM14 | c.742C>T p.Q248* | Nonsense Mutation (SNP) | VAF 25/108 reads (23%) | catalogued as COSV99400483; called by muse, mutect2, varscan2
- PRR19 | c.214G>A p.E72K | Missense Mutation (SNP) | VAF 55/261 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.027); catalogued as COSV100004098; called by muse, mutect2, varscan2
- PTBP1 | c.1391C>G p.S464* (on ENST00000349038 / NM_031991.4; = p.S490* on NM_002819.5) | Nonsense Mutation (SNP) | VAF 27/85 reads (32%) | catalogued as COSV100609046, COSV62461621; called by muse, mutect2, varscan2
- PTPRB | c.4255A>G p.K1419E | Missense Mutation (SNP) | VAF 19/103 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99718780; called by muse, mutect2, varscan2
- PXDN | c.2131C>G p.P711A | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.94); catalogued as COSV99414781; called by muse, mutect2, varscan2
- PYHIN1 | c.1104A>T p.K368N | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.474); catalogued as COSV100932407, COSV63722342; called by muse, mutect2, varscan2
- RALGAPA2 | c.4711G>C p.E1571Q | Missense Mutation (SNP) | VAF 22/86 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99174895; called by muse, mutect2, varscan2
- RELN | c.6139T>A p.F2047I | Missense Mutation (SNP) | VAF 5/67 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.007); catalogued as COSV100634808; called by muse, mutect2
- REV3L | c.2641A>G p.T881A | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as rs1038542327, COSV100725656; called by muse, mutect2, varscan2
- REXO5 | c.1295A>T p.K432M | Missense Mutation (SNP) | VAF 43/154 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99759457; called by muse, mutect2, varscan2
- ROBO2 | c.3020G>A p.S1007N | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.031); catalogued as COSV100169647; called by muse, mutect2, varscan2
- RTN1 | c.739G>T p.G247* | Nonsense Mutation (SNP) | VAF 59/191 reads (31%) | catalogued as COSV99956723; called by muse, mutect2, varscan2
- RYR3 | c.1915G>A p.V639I | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.427); catalogued as COSV66810597; called by muse, mutect2
- RYR3 | c.6723G>T p.L2241F | Missense Mutation (SNP) | VAF 28/185 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); catalogued as COSV100774411; called by muse, mutect2, varscan2
- RYR3 | c.7988A>G p.E2663G (on ENST00000389232; = p.E2664G on NM_001036.6) | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV101214257, COSV66809938; called by muse, mutect2, varscan2
- SCRIB | c.3019C>G p.L1007V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.045); catalogued as COSV100254051; called by muse, mutect2
- SHANK2 | c.4603G>C p.D1535H | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM121512, COSV53604152, COSV99575874; called by muse, mutect2
- SHROOM4 | c.757C>G p.Q253E | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated (0.15); PolyPhen benign (0.057); catalogued as COSV99174524; called by muse, mutect2
- SLAIN1 | c.1445C>A p.P482Q (on ENST00000466548; = p.P219Q on NM_144595.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/100 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99935464; called by muse, mutect2, varscan2
- SLC13A3 | c.686A>T p.N229I | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.766); catalogued as rs1274275677, COSV51715310, COSV99287210; called by muse, mutect2, varscan2
- SLC2A1 | c.863A>G p.N288S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV100995958; called by muse, mutect2, varscan2
- SLC35B1 | c.385A>G p.I129V (on ENST00000649906; = p.I92V on NM_005827.4) | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs754087225, COSV99539642; called by muse, mutect2, varscan2
- SLC4A4 | c.1436C>T p.A479V (on ENST00000264485 / NM_001098484.3; = p.A435V on NM_003759.4) | Missense Mutation (SNP) | VAF 45/260 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.403); catalogued as COSV99142044; called by muse, mutect2, varscan2
- SLCO2A1 | c.1411C>T p.H471Y | Missense Mutation (SNP) | VAF 167/466 reads (36%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.521); catalogued as COSV100189303; called by muse, mutect2, varscan2
- SNX30 | c.643G>A p.G215R | Missense Mutation (SNP) | VAF 122/243 reads (50%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV100953961; called by muse, mutect2, varscan2
- SORCS3 | c.2737C>A p.P913T | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV100863789; called by muse, mutect2, varscan2
- SPATA13 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV100542511; called by muse, mutect2, varscan2
- SPATA16 | c.1572G>C p.W524C | Missense Mutation (SNP) | VAF 20/158 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100651586; called by muse, varscan2
- SPTA1 | c.5554G>T p.A1852S | Missense Mutation (SNP) | VAF 38/206 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.306); catalogued as COSV100935505; called by muse, mutect2, varscan2
- SPTA1 | c.2218C>A p.Q740K | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as COSV100935247, COSV100935507; called by muse, mutect2, varscan2
- SRFBP1 | c.749G>C p.G250A | Missense Mutation (SNP) | VAF 51/160 reads (32%) | SIFT tolerated (0.16); PolyPhen benign (0.039); catalogued as COSV100232941, COSV59582249; called by muse, mutect2, varscan2
- STARD3 | c.901A>T p.I301F | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.513); catalogued as COSV99988413; called by muse, mutect2, varscan2
- STK11IP | c.1736G>T p.R579L | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753232181, COSV99823328; called by muse, varscan2
- SYT1 | c.496G>C p.A166P | Missense Mutation (SNP) | VAF 29/126 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99697245; called by muse, mutect2, varscan2
- TAS1R3 | c.829G>A p.V277M | Missense Mutation (SNP) | VAF 8/16 reads (50%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.677); catalogued as rs748214052, COSV100229820; called by muse, varscan2
- TBC1D15 | c.1834C>G p.L612V | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.02); catalogued as COSV100042211; called by muse, mutect2, varscan2
- TCHHL1 | c.1685C>G p.S562* | Nonsense Mutation (SNP) | VAF 42/201 reads (21%) | catalogued as COSV100916602; called by muse, mutect2, varscan2
- TIAM1 | c.1849G>A p.D617N | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV99738521; called by muse, mutect2, varscan2
- TLE3 | c.923A>G p.D308G | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV100450830; called by muse, mutect2, varscan2
- TMC3 | c.2697dup p.H900Tfs*17 | Frame Shift Ins (INS) | VAF 14/144 reads (10%) | catalogued as rs776122233; called by mutect2, pindel
- TTN | c.74217G>C p.M24739I (on ENST00000591111; = p.M17315I on NM_003319.4) | Missense Mutation (SNP) | VAF 67/249 reads (27%) | PolyPhen benign (0.051); catalogued as COSV100627829; called by muse, mutect2, varscan2
- TTN | c.32179G>A p.E10727K (on ENST00000591111; = p.E9800K on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 26/112 reads (23%) | PolyPhen benign (0.007); catalogued as COSV100627830; called by muse, mutect2, varscan2
- UBE2M | c.352G>A p.D118N | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99448338; called by muse, mutect2, varscan2
- ULK1 | c.551C>T p.S184F | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100417228; called by muse, mutect2, varscan2
- USH2A | c.11722G>A p.G3908S | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.102); catalogued as COSV100241814; called by muse, mutect2, varscan2
- USP32 | c.2582G>T p.W861L | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT tolerated (0.78); PolyPhen benign (0.001); catalogued as COSV100342753; called by muse, mutect2, varscan2
- USP34 | c.3076G>C p.D1026H | Missense Mutation (SNP) | VAF 53/225 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101277194; called by muse, mutect2, varscan2
- VPS13C | c.9154G>C p.V3052L (on ENST00000644861 / NM_020821.3; = p.V3009L on NM_017684.5) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.667); catalogued as COSV99830035; called by muse, mutect2, varscan2
- WASF3 | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100099440; called by muse, mutect2, varscan2
- WDR45B | c.685C>G p.Q229E | Missense Mutation (SNP) | VAF 30/138 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV101124431, COSV66408778; called by muse, mutect2, varscan2
- XKR7 | c.173G>T p.C58F | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV101629296; called by muse, mutect2
- ZBED4 | c.1441G>A p.G481S | Missense Mutation (SNP) | VAF 51/310 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs760669604, COSV99351625; called by muse, mutect2, varscan2
- ZBED6CL | c.224C>G p.T75S | Missense Mutation (SNP) | VAF 40/150 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100550618; called by muse, mutect2, varscan2
- ZBP1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as COSV100473891; called by muse, varscan2
- ZBTB2 | c.973G>C p.D325H | Missense Mutation (SNP) | VAF 11/129 reads (9%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV100287828; called by muse, mutect2
- ZBTB4 | c.1409C>G p.S470C | Missense Mutation (SNP) | VAF 19/45 reads (42%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.887); catalogued as COSV100263723; called by muse, mutect2, varscan2
- ZNF214 | c.1753C>A p.R585S | Missense Mutation (SNP) | VAF 14/86 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs570929738, COSV99547632; called by muse, mutect2, varscan2
- ZNF384 | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.87); PolyPhen benign (0.012); catalogued as rs961320179, COSV100158860; called by muse, mutect2, varscan2
- ZNF391 | c.832G>A p.E278K | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.225); catalogued as COSV99772802; called by muse, mutect2, varscan2
- ZNF430 | c.1037A>T p.K346I | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV99841983; called by muse, mutect2, varscan2
- ZNF438 | c.1182G>C p.L394F | Missense Mutation (SNP) | VAF 32/158 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs188022216, COSV100062638; called by muse, mutect2, varscan2
- ZNF516 | c.1658G>T p.R553L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.05); PolyPhen benign (0.268); catalogued as COSV101487361, COSV71586661; called by muse, varscan2
- ZNF721 | c.2414C>T p.A805V (on ENST00000338977; = p.A817V on NM_133474.4) | Missense Mutation (SNP) | VAF 32/90 reads (36%) | SIFT tolerated (0.13); PolyPhen benign (0.075); catalogued as rs782289856, COSV59089724; called by muse, mutect2, varscan2
- ZNF804B | c.2120G>A p.R707K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0); catalogued as COSV60821510, COSV60858147; called by muse, mutect2, varscan2
- ZNF85 | c.392G>T p.C131F | Missense Mutation (SNP) | VAF 37/148 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV56020933, COSV56021327; called by muse, mutect2, varscan2
- ZNF93 | c.451G>T p.G151W | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as COSV100652419; called by muse, mutect2, varscan2
- APAF1 | c.910del p.A304Qfs*11 (on ENST00000551964 / NM_181861.2; = p.A293Qfs*11 on NM_001160.3) | Frame Shift Del (DEL) | VAF 12/70 reads (17%) | called by mutect2, pindel, varscan2
- CD2AP | c.763_765del p.Q255del | In Frame Del (DEL) | VAF 25/211 reads (12%) | called by mutect2, pindel, varscan2
- CPSF7 | c.152_161del p.P51Lfs*45 (on ENST00000394888 / NM_001136040.4; = p.P94Lfs*45 on NM_024811.4) | Frame Shift Del (DEL) | VAF 11/63 reads (17%) | called by mutect2, pindel, varscan2
- MARCHF3 | c.223del p.H75Tfs*55 | Frame Shift Del (DEL) | VAF 7/36 reads (19%) | called by mutect2, pindel
- MROH1 | c.1964C>T p.T655I | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated (0.24); PolyPhen benign (0.444); called by muse, mutect2
- MTA2 | c.385dup p.Y129Lfs*6 | Frame Shift Ins (INS) | VAF 28/206 reads (14%) | called by mutect2, varscan2
- OR5AP2 | c.345del p.T116Lfs*8 | Frame Shift Del (DEL) | VAF 6/53 reads (11%) | called by mutect2, pindel, varscan2
- SPATA31A1 | c.709C>A p.P237T | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ZNF135 | c.160+1del | Frame Shift Del (DEL) | VAF 38/182 reads (21%) | called by mutect2, pindel, varscan2
- ABCA13 | c.3729T>G p.V1243= | Silent (SNP) | VAF 23/67 reads (34%) | catalogued as COSV101330165; called by muse, mutect2, varscan2
- ABCB4 | c.714C>T p.L238= | Silent (SNP) | VAF 39/173 reads (23%) | catalogued as COSV99711187; called by muse, mutect2, varscan2
- ABCG1 | c.1773G>T p.T591= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100494490; called by muse, mutect2, varscan2
- ACTRT2 | c.1023C>A p.T341= | Silent (SNP) | VAF 59/185 reads (32%) | catalogued as COSV101007662; called by muse, mutect2, varscan2
- ADCY10 | c.2265G>C p.T755= | Silent (SNP) | VAF 13/141 reads (9%) | catalogued as COSV63242505, COSV63242550; called by muse, mutect2
- ATG2A | c.4932G>A p.S1644= | Silent (SNP) | VAF 11/69 reads (16%) | catalogued as rs756185517, COSV65967222; called by muse, mutect2, varscan2
- BCL11B | c.999G>A p.E333= (on ENST00000357195 / NM_001282237.2; = p.E262= on NM_022898.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 3/10 reads (30%) | catalogued as rs1473508245, COSV100595854; called by muse, mutect2
- BRSK2 | c.1560C>T p.S520= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV100373121; called by muse, mutect2, varscan2
- CA1 | c.754C>T p.L252= | Silent (SNP) | VAF 36/153 reads (24%) | catalogued as COSV99810344; called by muse, mutect2, varscan2
- CADPS2 | c.3727A>C p.R1243= | Silent (SNP) | VAF 64/251 reads (25%) | catalogued as COSV100465607; called by muse, mutect2, varscan2
- CD180 | c.12C>T p.D4= | Silent (SNP) | VAF 11/156 reads (7%) | catalogued as rs758826950, COSV56517550, COSV99842374; called by muse, mutect2
- CELSR1 | c.7467C>A p.L2489= | Silent (SNP) | VAF 26/62 reads (42%) | catalogued as COSV99419845; called by muse, mutect2, varscan2
- CPS1 | c.1540C>T p.L514= | Silent (SNP) | VAF 26/115 reads (23%) | catalogued as rs890185470, COSV99243970; called by muse, mutect2, varscan2
- DSCAM | c.4083C>A p.A1361= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV68037525; called by muse, mutect2, varscan2
- DSEL | c.1251A>G p.A417= | Silent (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100026063; called by muse, mutect2, varscan2
- ERMN | c.678C>A p.S226= | Silent (SNP) | VAF 49/241 reads (20%) | catalogued as COSV101263065; called by muse, mutect2, varscan2
- ETNPPL | c.1041G>A p.L347= | Silent (SNP) | VAF 21/93 reads (23%) | catalogued as COSV56596966; called by muse, mutect2, varscan2
- FRAS1 | c.10161G>C p.L3387= | Silent (SNP) | VAF 42/183 reads (23%) | catalogued as COSV53626583, COSV99355465; called by muse, mutect2, varscan2
- GNL1 | c.609T>C p.N203= | Silent (SNP) | VAF 7/88 reads (8%) | catalogued as COSV100925448; called by muse, mutect2
- HEPH | c.1365C>A p.I455= (on ENST00000343002; = p.I188= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV100295618, COSV57959397; called by muse, mutect2, varscan2
- HOXC9 | c.711A>G p.K237= | Silent (SNP) | VAF 29/117 reads (25%) | catalogued as COSV100327628; called by muse, mutect2, varscan2
- HS3ST3B1 | c.1020G>A p.A340= | Silent (SNP) | VAF 34/137 reads (25%) | catalogued as rs774444816, COSV100714588; called by muse, varscan2
- HUWE1 | c.2106A>G p.P702= | Silent (SNP) | VAF 32/54 reads (59%) | catalogued as COSV99474060; called by muse, mutect2, varscan2
- KDM2B | c.2709G>A p.K903= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100997651; called by muse, mutect2, varscan2
- MAN1B1 | c.1870C>T p.L624= | Silent (SNP) | VAF 93/186 reads (50%) | catalogued as COSV100857410; called by muse, mutect2, varscan2
- MEAK7 | c.225G>C p.L75= | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as COSV100640452; called by muse, mutect2, varscan2
- MED15 | c.282G>A p.A94= | Silent (SNP) | VAF 48/122 reads (39%) | catalogued as rs759898076, COSV99488109; called by muse, mutect2, varscan2
- MYH13 | c.5391G>A p.L1797= | Silent (SNP) | VAF 77/194 reads (40%) | catalogued as COSV99355326; called by muse, mutect2, varscan2
- NARS2 | c.102C>T p.L34= | Silent (SNP) | VAF 48/172 reads (28%) | catalogued as rs775020704, COSV99807507; called by muse, mutect2, varscan2
- NEK11 | c.324G>T p.T108= | Silent (SNP) | VAF 12/90 reads (13%) | catalogued as COSV100797575, COSV100797879; called by muse, mutect2, varscan2
- NELFE | c.543C>T p.S181= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as rs749131495, COSV64814814; called by muse, mutect2, varscan2
- ONECUT1 | c.351A>C p.T117= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as COSV100009412; called by muse, mutect2, varscan2
- OPN5 | c.69T>C p.P23= | Silent (SNP) | VAF 9/167 reads (5%) | called by muse, mutect2
- OR14I1 | c.396C>A p.A132= | Silent (SNP) | VAF 7/46 reads (15%) | called by mutect2, varscan2
- PCDHA1 | c.1146C>T p.N382= | Silent (SNP) | VAF 51/147 reads (35%) | catalogued as COSV65374740; called by muse, mutect2, varscan2
- PCDHGB1 | c.2382C>A p.I794= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as COSV53896849, COSV99546049; called by muse, varscan2
- PCLO | c.3174C>T p.T1058= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV100437143; called by muse, mutect2, varscan2
- PFKL | c.2199C>T p.H733= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs1364793032, COSV100297209; called by muse, mutect2, varscan2
- PHACTR2 | c.177G>A p.S59= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs201524736, COSV99992273; called by muse, mutect2, varscan2
- PNPLA7 | c.3624C>A p.G1208= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99481343; called by muse, varscan2
- POLR1F | c.9A>T p.A3= | Silent (SNP) | VAF 14/68 reads (21%) | catalogued as COSV99749049; called by muse, mutect2, varscan2
- POM121L12 | c.468G>A p.Q156= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as rs999710286, COSV68693431; called by muse, mutect2, varscan2
- PRICKLE2 | c.2296C>A p.R766= (on ENST00000295902; = p.R710= on NM_198859.4) | Silent (SNP) | VAF 21/91 reads (23%) | catalogued as COSV55762145, COSV99897981; called by muse, mutect2, varscan2
- RALGAPA1 | c.5517A>T p.V1839= | Silent (SNP) | VAF 37/151 reads (25%) | catalogued as COSV99355940; called by muse, mutect2, varscan2
- SATB2 | c.2085G>T p.L695= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as COSV99611036; called by muse, mutect2, varscan2
- SF3A1 | c.1098G>A p.Q366= | Silent (SNP) | VAF 22/149 reads (15%) | catalogued as COSV99305695; called by muse, mutect2, varscan2
- SGSM1 | c.2253C>T p.P751= (on ENST00000400359 / NM_001039948.4; = p.P690= on NM_133454.3) | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV100771890; called by muse, mutect2, varscan2
- SLC6A4 | c.742C>T p.L248= | Silent (SNP) | VAF 36/128 reads (28%) | catalogued as rs76377611, COSV99911569; called by muse, mutect2, varscan2
- SLC9A2 | c.2028T>C p.L676= | Silent (SNP) | VAF 35/113 reads (31%) | catalogued as rs774679914, COSV99296727; called by muse, mutect2, varscan2
- SORCS1 | c.279G>T p.R93= | Silent (SNP) | VAF 3/14 reads (21%) | catalogued as COSV99549889; called by muse, mutect2
- SPON1 | c.606C>T p.C202= | Silent (SNP) | VAF 24/62 reads (39%) | catalogued as rs782016066, COSV59964332; called by muse, mutect2, varscan2
- SRGAP2 | c.2064C>G p.V688= (on ENST00000624873 / NM_001170637.4; = p.V689= on NM_015326.5 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 54/240 reads (23%) | catalogued as COSV99833229; called by muse, mutect2, varscan2
- STRA6 | c.1908G>A p.R636= | Silent (SNP) | VAF 63/219 reads (29%) | catalogued as rs763698147, COSV99997534; called by muse, mutect2, varscan2
- SULF1 | c.1017T>G p.R339= | Silent (SNP) | VAF 80/376 reads (21%) | catalogued as COSV99483376, COSV99484243; called by muse, mutect2, varscan2
- SYCP1 | c.1302A>G p.E434= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as rs755023783, COSV101051179; called by muse, mutect2, varscan2
- TOMM70 | c.1098A>T p.R366= | Silent (SNP) | VAF 40/241 reads (17%) | catalogued as COSV99424572; called by muse, mutect2, varscan2
- TPH2 | c.1008A>G p.S336= | Silent (SNP) | VAF 40/177 reads (23%) | catalogued as COSV61594567; called by muse, mutect2, varscan2
- TPK1 | c.81T>A p.P27= | Silent (SNP) | VAF 25/120 reads (21%) | catalogued as COSV100766047; called by muse, mutect2, varscan2
- TPRX1 | c.1194G>A p.V398= | Silent (SNP) | VAF 37/153 reads (24%) | catalogued as rs769056054, COSV100445876; called by muse, mutect2, varscan2
- UBFD1 | c.687G>A p.V229= | Silent (SNP) | VAF 26/97 reads (27%) | catalogued as rs768255871, COSV99563450; called by muse, mutect2, varscan2
- VPS13C | c.10461A>G p.K3487= (on ENST00000644861 / NM_020821.3; = p.K3444= on NM_017684.5) | Silent (SNP) | VAF 56/195 reads (29%) | catalogued as COSV99830030; called by muse, mutect2, varscan2
- WBP2NL | c.159C>G p.L53= | Silent (SNP) | VAF 38/137 reads (28%) | catalogued as COSV60920881; called by muse, mutect2, varscan2
- WDR27 | c.2196G>A p.R732= | Silent (SNP) | VAF 4/43 reads (9%) | catalogued as COSV100359717; called by muse, mutect2
- WSCD2 | c.279C>T p.F93= | Silent (SNP) | VAF 38/149 reads (26%) | catalogued as COSV99775184; called by muse, mutect2, varscan2
- ZNF696 | c.570C>T p.F190= | Silent (SNP) | VAF 14/47 reads (30%) | catalogued as rs1020394009, COSV100350639; called by muse, mutect2
- ASCC3 | c.241+4894G>A | Intron (SNP) | VAF 25/92 reads (27%) | catalogued as COSV100226255; called by muse, mutect2, varscan2
- ASIC2 | c.556-179551C>T | Intron (SNP) | VAF 13/42 reads (31%) | catalogued as rs751416838, COSV99860968; called by muse, mutect2, varscan2
- CEP295 | chr11:93730642 G>A | 3'Flank (SNP) | VAF 19/154 reads (12%) | catalogued as rs775417816; called by muse, mutect2, varscan2
- DCHS2 | n.6980G>T | RNA (SNP) | VAF 40/132 reads (30%) | catalogued as COSV61772310; called by muse, mutect2, varscan2
- DCHS2 | n.6774T>C | RNA (SNP) | VAF 8/133 reads (6%) | catalogued as COSV100602561; called by muse, mutect2
- DPP6 | c.627+20874C>G | Intron (SNP) | VAF 7/25 reads (28%) | catalogued as COSV100127883; called by muse, mutect2, varscan2
- HLA-DRB9 | n.114G>C | RNA (SNP) | VAF 43/146 reads (29%) | called by muse, mutect2, varscan2
- NXF5 | n.566T>C | RNA (SNP) | VAF 8/188 reads (4%) | catalogued as COSV99534630; called by muse, mutect2
